Somatic mutation profile of tumor specimen TCGA-D1-A3JP-01A (aliquot TCGA-D1-A3JP-01A-31D-A228-09) from TCGA case TCGA-D1-A3JP, project TCGA-UCEC (Uterine Corpus Endometrial Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Serous cystadenocarcinoma, NOS; Tissue or organ of origin: Endometrium; FIGO stage: Stage IA; Tumor grade: G3; Age at diagnosis: 61.7 years (22,538 days).
Specimen TCGA-D1-A3JP-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) e6c0d69e-bcec-4e05-a8f1-70e76c0ffca7.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-D1-A3JP-10B (Blood Derived Normal), aliquot TCGA-D1-A3JP-10B-01D-A22A-09; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/c66f5655-f66f-40ad-a7c7-316caf33aeb0

The open-access MAF lists 55 somatic variants for this specimen: 35 protein-altering or splice-affecting, 20 silent.
By variant classification: Missense Mutation 29, Silent 20, Frame Shift Del 2, Splice Region 1, Translation Start Site 1, In Frame Ins 1, Splice Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- FBXW7 | c.1268G>T p.G423V (on ENST00000281708 / NM_001349798.2; = p.G343V on NM_018315.5) | Missense Mutation (SNP) | VAF 12/67 reads (18%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1157879635, COSV55892390, COSV99657129; called by muse, mutect2, varscan2
- SOS1 | c.697A>T p.N233Y | Missense Mutation (SNP) | VAF 11/44 reads (25%) | hotspot (GDC flag); SIFT tolerated (1); PolyPhen possibly damaging (0.671); catalogued as rs1057519963, COSV67673722; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- TP53 | c.659A>G p.Y220C | Missense Mutation (SNP) | VAF 20/38 reads (53%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs121912666, CM015378, CM951227, COSV52661282, COSV52677517; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- CCDC185 | c.560C>T p.S187L | Missense Mutation (SNP) | VAF 177/191 reads (93%) | SIFT tolerated (0.1); PolyPhen benign (0.003); catalogued as COSV100838811; called by muse, mutect2, varscan2
- CEP63 | c.433A>G p.K145E | Missense Mutation (SNP) | VAF 16/46 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.909); catalogued as COSV100132826; called by muse, mutect2, varscan2
- COL12A1 | c.4900G>A p.V1634I | Missense Mutation (SNP) | VAF 4/36 reads (11%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.776); catalogued as rs772992461, COSV100486153; called by mutect2, varscan2
- CTAGE6 | c.1267C>G p.L423V | Missense Mutation (SNP) | VAF 30/200 reads (15%) | SIFT deleterious (0.01); PolyPhen benign (0); catalogued as COSV101417822, COSV101417858; called by muse, mutect2, varscan2
- DNAH10 | c.3565G>A p.D1189N (on ENST00000409039; = p.D1128N on NM_207437.3) | Missense Mutation (SNP) | VAF 3/48 reads (6%) | SIFT deleterious (0.03); PolyPhen benign (0.098); catalogued as COSV68988918; called by muse, mutect2
- ENTPD6 | c.106G>A p.G36R | Missense Mutation (SNP) | VAF 4/20 reads (20%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.963); catalogued as rs1017811642, COSV100737107; called by muse, mutect2, varscan2
- FAM217A | c.1060A>G p.K354E | Missense Mutation (SNP) | VAF 10/57 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV99212740; called by muse, mutect2, varscan2
- FBH1 | c.1697C>T p.S566L (on ENST00000362091 / NM_178150.3; = p.S617L on NM_032807.4) | Missense Mutation (SNP) | VAF 7/56 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs773741923, COSV100758794; called by muse, mutect2, varscan2
- FBXO44 | c.199G>C p.D67H | Missense Mutation (SNP) | VAF 20/73 reads (27%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.986); catalogued as COSV52353544, COSV99278991; called by muse, mutect2, varscan2
- FGA | c.1860G>C p.K620N | Missense Mutation (SNP) | VAF 5/53 reads (9%) | SIFT tolerated (0.11); PolyPhen benign (0.386); catalogued as rs766366023, COSV100120459; called by mutect2, varscan2
- GRIA2 | c.1771G>A p.E591K | Missense Mutation (SNP) | VAF 4/34 reads (12%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.869); catalogued as COSV99644788; called by muse, mutect2, varscan2
- HDX | c.593G>A p.G198E | Missense Mutation (SNP) | VAF 26/51 reads (51%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.617); catalogued as COSV99947502; called by muse, mutect2, varscan2
- HMOX2 | c.696+1G>A p.X232_splice | Splice Site (SNP) | VAF 22/55 reads (40%) | catalogued as COSV99566591; called by muse, mutect2, varscan2
- LRR1 | c.675G>C p.Q225H | Missense Mutation (SNP) | VAF 5/34 reads (15%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.819); catalogued as COSV100023174; called by mutect2, varscan2
- MEIS3 | c.661T>G p.S221A | Missense Mutation (SNP) | VAF 13/61 reads (21%) | SIFT tolerated (0.21); PolyPhen benign (0.023); catalogued as COSV100520483; called by muse, mutect2, varscan2
- MGAT2 | c.1331G>C p.R444T | Missense Mutation (SNP) | VAF 6/35 reads (17%) | SIFT tolerated (0.38); PolyPhen benign (0.113); catalogued as rs979777755, COSV100023572; called by muse, mutect2, varscan2
- MIEF1 | c.1324G>A p.E442K | Missense Mutation (SNP) | VAF 8/76 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as COSV100307729, COSV57477938; called by muse, mutect2, varscan2
- OR5D16 | c.475C>G p.L159V | Missense Mutation (SNP) | VAF 23/50 reads (46%) | SIFT deleterious (0.04); PolyPhen benign (0.254); catalogued as COSV101004014; called by muse, mutect2, varscan2
- OR5D16 | c.805T>A p.S269T | Missense Mutation (SNP) | VAF 14/35 reads (40%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.82); catalogued as COSV101004016; called by muse, mutect2, varscan2
- PAXIP1 | c.919G>A p.E307K | Missense Mutation (SNP) | VAF 4/22 reads (18%) | SIFT tolerated, low confidence (0.05); PolyPhen possibly damaging (0.714); catalogued as COSV101249806; called by muse, mutect2
- PCDHB7 | c.2165G>A p.R722H | Missense Mutation (SNP) | VAF 16/234 reads (7%) | SIFT tolerated, low confidence (0.13); PolyPhen possibly damaging (0.556); catalogued as COSV50773233; called by muse, mutect2
- PLAG1 | c.307C>T p.R103W | Missense Mutation (SNP) | VAF 7/12 reads (58%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as COSV57611568; called by muse, mutect2, varscan2
- PVRIG | c.3G>A p.M1? | Translation Start Site (SNP) | VAF 13/57 reads (23%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.168); catalogued as rs867004449, COSV99443916; called by muse, mutect2, varscan2
- RPS6KA3 | c.1537G>C p.E513Q | Missense Mutation (SNP) | VAF 9/53 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV101084459, COSV65389190; called by muse, mutect2, varscan2
- SCRIB | c.2068G>A p.E690K | Missense Mutation (SNP) | VAF 5/31 reads (16%) | SIFT tolerated (0.26); PolyPhen benign (0.138); catalogued as COSV100253612; called by muse, mutect2, varscan2
- SERPINA6 | c.176C>T p.P59L | Missense Mutation (SNP) | VAF 5/37 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV100448195, COSV100448324; called by mutect2, varscan2
- SLC8A3 | c.1550G>C p.C517S | Missense Mutation (SNP) | VAF 4/34 reads (12%) | SIFT tolerated (0.45); PolyPhen benign (0); catalogued as rs775287620, COSV100775782, COSV100776261; called by mutect2, varscan2
- TOM1L1 | c.708A>G p.I236M | Missense Mutation (SNP) | VAF 7/51 reads (14%) | SIFT tolerated (1); PolyPhen benign (0.009); catalogued as COSV100779236; called by muse, mutect2, varscan2
- ARHGEF10 | c.2932_2957del p.P978* (on ENST00000398564; = p.P953* on NM_014629.4) | Frame Shift Del (DEL) | VAF 5/27 reads (19%) | called by mutect2, pindel
- ASTN1 | c.2943C>T p.L981= | Splice Region (SNP) | VAF 4/12 reads (33%) | called by mutect2, varscan2
- DMRTB1 | c.806del p.P269Rfs*41 | Frame Shift Del (DEL) | VAF 12/67 reads (18%) | called by mutect2, pindel*, varscan2
- SCAF11 | c.127_129dup p.I43dup | In Frame Ins (INS) | VAF 6/32 reads (19%) | called by mutect2, pindel, varscan2
- ACAN | c.5358T>C p.S1786= | Silent (SNP) | VAF 13/74 reads (18%) | catalogued as rs902209343, COSV100718376; called by muse, mutect2, varscan2
- ACOT2 | c.582C>A p.P194= | Silent (SNP) | VAF 6/29 reads (21%) | catalogued as COSV99469057; called by muse, mutect2, varscan2
- DSPP | c.2526C>T p.S842= | Silent (SNP) | VAF 20/47 reads (43%) | catalogued as rs899663071; called by muse, mutect2, varscan2
- FANCL | c.600C>T p.F200= | Silent (SNP) | VAF 11/57 reads (19%) | catalogued as rs1194137687, COSV52073738; called by muse, mutect2, varscan2
- GLRA4 | c.477T>C p.N159= | Silent (SNP) | VAF 6/37 reads (16%) | catalogued as rs1224902835, COSV101009657; called by muse, mutect2, varscan2
- HRNR | c.8505T>C p.T2835= | Silent (SNP) | VAF 6/55 reads (11%) | catalogued as COSV100913594; called by muse, mutect2, varscan2
- MAGEB6 | c.1215G>A p.L405= | Silent (SNP) | VAF 10/44 reads (23%) | catalogued as rs771894400, COSV100983770; called by muse, mutect2, varscan2
- PCDHA11 | c.381C>T p.N127= | Silent (SNP) | VAF 28/59 reads (47%) | catalogued as rs782167038, COSV100251431; called by muse, mutect2, varscan2
- PGLYRP1 | c.165C>A p.R55= | Silent (SNP) | VAF 4/50 reads (8%) | called by muse, mutect2
- PTPN12 | c.1785C>T p.L595= | Silent (SNP) | VAF 11/55 reads (20%) | catalogued as rs371650087; called by muse, mutect2, varscan2
- PXDN | c.3342C>T p.I1114= | Silent (SNP) | VAF 20/52 reads (38%) | catalogued as rs769083609, COSV99413889; called by muse, mutect2, varscan2
- RAB20 | c.12C>G p.P4= | Silent (SNP) | VAF 15/50 reads (30%) | catalogued as COSV99940908; called by muse, mutect2, varscan2
- RCN1 | c.963G>C p.G321= | Silent (SNP) | VAF 5/57 reads (9%) | catalogued as COSV50014902, COSV99277305; called by muse, mutect2
- RNASEH1 | c.642G>A p.T214= | Silent (SNP) | VAF 12/82 reads (15%) | catalogued as COSV59439400; called by muse, mutect2, varscan2
- RRP36 | c.283C>T p.L95= | Silent (SNP) | VAF 4/58 reads (7%) | catalogued as COSV99763808; called by muse, mutect2
- SHPRH | c.2466G>A p.Q822= | Silent (SNP) | VAF 5/51 reads (10%) | catalogued as COSV99262237; called by mutect2, varscan2
- SON | c.4089G>A p.S1363= | Silent (SNP) | VAF 11/32 reads (34%) | catalogued as rs925138731, COSV99278865; called by muse, mutect2, varscan2
- TNIK | c.3345T>G p.L1115= | Silent (SNP) | VAF 11/78 reads (14%) | catalogued as rs1376291543, COSV99457821; called by muse, mutect2, varscan2
- TRAM1L1 | c.42C>T p.L14= | Silent (SNP) | VAF 5/15 reads (33%) | catalogued as COSV100162266; called by muse, mutect2, varscan2
- UST | c.669G>A p.E223= | Silent (SNP) | VAF 11/28 reads (39%) | catalogued as rs1226760827, COSV100820045; called by muse, mutect2, varscan2
